Surgical pathology report (de-identified scan), TCGA case TCGA-43-A474, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Christiana Healthcare, specimen TCGA-43-A474-01A (Primary Tumor).

[page 1 of 3]
100-03

Carcinoma, Squamous
cell, NOS 807013

Site: lung, upper
lobe, bronchus
C34,1

Final Surgical Pathology Report

Procedure:

Diagnosis

E. and F. Lung, Left Upper Lobe lobectomy and subsequent bronchial margin:

Invasive squamous cell carcinoma, poorly differentiated, 5.6 cm (pT2b)

Tumor involves the main bronchus

Final bronchial margin (specimen F.) negative for tumor

Pleura negative for malignancy

No lymphatic or vascular space invasion identified

Venous and arterial margins negative for tumor

4 peribronchial lymph nodes negative for tumor (0/4)

K. Completion left pneumonectomy:

Pulmonary hemorrhage compatible with procedural effects

Focal hemosiderin compatible with more remote hemorrhage

Atelectasis

Bronchial and vascular margins unremarkable

A. Lymph node level #5, biopsy: Single lymph node negative for metastatic tumor (0/1)

B. Lymph node, level #6, biopsy: Single lymph node negative for metastatic tumor (0/1)

C. Lymph node, level #4, biopsy: Single lymph node negative for metastatic tumor (0/1)

D. Lymph node, level #9, biopsy: Single lymph node negative for metastatic tumor (0/1)

G. Lymph node, level #11, biopsy: Single lymph node negative for metastatic tumor (0/1)

H. Lymph node, level #7, biopsy: Single lymph node negative for metastatic tumor (0/1)

I. Lymph node, level #4, biopsy: Single lymph node negative for metastatic tumor (0/1)

J. Lymph node, level #10, biopsy: Single lymph node negative for metastatic tumor (0/1).

Microscopic Description:

A-J. Microscopic examination performed and summarized in the template below:

Histologic type: Invasive squamous carcinoma

Histologic grade: Poorly differentiated

Primary tumor (pT): 5.6 cm in greatest dimension (pT2b)

Margins of resection: Final bronchial margin in specimen F. negative for tumor. Bronchial margins negative for tumor

Direct extension of tumor: Tumor involves the main bronchus of the left upper lobe and invades pulmonary parenchyma. No extension into the pleura is identified.

Venous (large vessel) invasion: Negative

Arterial (large vessel) invasion: Negative

Lymphatic (small vessel) invasion: Negative

Regional lymph nodes (pN): All examined lymph nodes are negative for malignancy. Prominent anthracosis is present. (pN0)

Distant metastasis (pM): Not evaluated (pMX)

Other findings: Mild emphysematous change is present. Areas of anthracosis are present. Some bronchiectasis and some nonspecific focal interstitial fibrosis is noted away from the main tumor in the left upper lobe. The left lower lobe is notable for marked hemorrhage within the alveoli and prominent atelectasis. Anthracosis and hemosiderin laden macrophages are also prominent. No malignancy is identified in the left lower lobe.

9-5-12
RD

[page 2 of 3]
Specimen

- A. Level #5 lymph node, biopsy
- B. Level #6 lymph node, biopsy
- C. Level #4 lymph node, biopsy
- D. Level #9 lymph nodes, biopsy:
- E. Lung, left upper lobe, lobectomy
- F. Bronchial margin
- G. Level #11 lymph node, biopsy
- H. Level #7 node
- I. Level #4 node
- J. Level #10 node
- K. Completion left pneumonectomy

Clinical Information

Lung cancer

Intraoperative Consultation

- E. Lung left upper lobe, excision: Non-small cell carcinoma, consistent with squamous cell carcinoma on frozen section.
- F. Bronchial margin: Negative for malignancy.

Gross Description

- A. Received fresh and subsequently fixed in formalin labeled "level #5 node "is a 1.0 x 0.6 x 0.5 cm gray-tan irregular soft nodular tissue fragment which is bisected and entirely submitted in one cassette. AS1
- B. Received fresh and subsequently fixed in formalin labeled "level #6 node "is a 1.3 x 1.2 x 0.8 cm gray-tan nodular tissue fragment. The specimen is trisected and entirely submitted in one cassette. AS1
- C. Received fresh and subsequently fixed in formalin labeled "level #4 node "is a 0.3 x 0.2 x 0.2 cm gray-tan irregular nodular tissue fragment which is entirely submitted in one cassette. AS1.
- D. Received fresh and subsequently fixed in formalin labeled "level #9 node "is a 0.3 x 0.3 x 0.3 cm black red irregular soft tissue fragment. AS1.
- E. Received fresh and subsequently fixed in formalin labeled "left upper lobe of lung "is a 26.0 x 16.0 x 6.0 cm lobe of lung. The specimen is partially covered with a pink-tan smooth glistening pleura showing diffuse black stippling. The specimen shows a firm mass near the hilar surface. No discrete pleura umbilication is grossly identified however the mass can be palpated. The specimen is sectioned to show a large white tan ill circumscribed lesion which is 5.6 x 5.5 x 4.3 cm. It does not appear to grossly involve the pleura surface and comes within 0.2 cm of the bronchial margin. Tumor is grossly present within the bronchus. No discrete hilar nodes are grossly identified. The remainder of the cut surface of the specimen is pink red and spongy with diffuse black stippling present. Representative sections of the specimen are submitted as follows: 1 - bronchial and vascular margins, 2 - tumor to pleura, 3 - tumor in bronchus, 4 - possible hilar nodes bisected, 5 - tumor to normal, 6 - additional tumor to normal, 7 - representative normal. RS 7.
- F. Received fresh for frozen section labeled "F. bronchial margin" is a 4 x 0.6 x 0.6 cm piece of stapled tan rubbery cartilaginous tissue. The staples are removed and the specimen is frozen as frozen section FFS 1.
- G. Received fresh and subsequently fixed in formalin labeled "level #11 node "is a 0.6 x 0.5 x 0.3 cm black red irregular soft tissue fragment which is bisected and entirely submitted in one cassette. AS1.
- H. Received fresh and subsequently fixed in formalin labeled "level #7 node "is a 2.2 x 1.5 x 0.5 cm gray-tan irregular nodular tissue fragment is bisected and entirely submitted in 2 cassettes
- I. Received fresh and subsequently fixed in formalin labeled "level #4 node "is a 1.0 x 0.6 x 0.5 cm gray-tan irregular soft tissue fragment which is bisected and entirely submitted in one cassette. AS1.

[page 3 of 3]
J. Received fresh and subsequently fixed in formalin labeled "labeled level #10 node" is a 1.2 x 0.6 x 0.5 cm gray-tan irregular nodule which is bisected and entirely submitted in one cassette. AS1.

K. Received fresh and subsequently fixed in formalin labeled "completion left pneumonectomy" is a 20.5 x 8.5 x 3.5 cm lobe of lung with an extended portion of bronchus measuring 5 cm in length. The pleura is violaceous smooth glistening with diffuse black stippling present. The specimen is palpated to identify no discrete gross lesions. The specimen is sectioned to show pink red spongy cut surface with no other discrete gross lesions identified. No discrete hilar lymph nodes are grossly identified. Representative sections of the specimen are submitted as follows: 1 - representative normal, 2 - bronchial margin, vascular margins with possible lymph node. 4 - 5 - additional representative sections of the specimen.

For Malignancy History		

8/23/12

Source: NCI Genomic Data Commons file fbf0cf53-f8df-4f73-9306-56a1f5bf5e6c (TCGA-43-A474.31549DED-DB58-4FA2-A598-29B34B12AF4E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).